Somatic mutation profile of tumor specimen TCGA-30-1853-01A (aliquot TCGA-30-1853-01A-02W-0699-08) from TCGA case TCGA-30-1853, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.6 years (21,404 days).
Specimen TCGA-30-1853-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f56177c-737b-4318-93f8-8b8be336769e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1853-10A (Blood Derived Normal), aliquot TCGA-30-1853-10A-01W-0699-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd7cb96-b452-41c7-a11d-8fc14ab6e5ed

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 400/410 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD18 | c.623C>T p.A208V (on ENST00000398965 / NM_001039717.2; = p.A81V on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761660121, COSV66294178; called by muse, mutect2, varscan2
- AHNAK2 | c.13088A>T p.D4363V | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV60919409; called by muse, mutect2, varscan2
- ANGPTL4 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56845033; called by muse, mutect2, varscan2
- BCAS1 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV65087380, COSV65089592; called by muse, mutect2, varscan2
- C12orf60 | c.671T>G p.I224S | Missense Mutation (SNP) | VAF 189/294 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs754984200, COSV57452396; called by muse, mutect2, varscan2
- CDH15 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.078); catalogued as rs753510634, COSV57025303, COSV99228499; called by muse, mutect2, varscan2
- CENPF | c.1866G>A p.W622* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV65273066, COSV65273078; called by muse, mutect2, varscan2
- COPG1 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363716962, COSV59114302; called by muse, mutect2, varscan2
- COPG1 | c.1577A>G p.D526G | Missense Mutation (SNP) | VAF 108/184 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59114989; called by muse, mutect2, varscan2
- DHX16 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV64564528; called by muse, varscan2
- DHX16 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV64564531; called by muse, varscan2
- ENPP4 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 388/394 reads (98%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.843); catalogued as COSV58088660; called by muse, mutect2, varscan2
- FAM83D | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 47/61 reads (77%) | catalogued as COSV54158003; called by muse, mutect2, varscan2
- GCOM1 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 123/349 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51092529; called by muse, mutect2, varscan2
- ITGB6 | c.1567A>G p.I523V | Missense Mutation (SNP) | VAF 101/204 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51795832; called by muse, mutect2, varscan2
- LRRTM4 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV69140776; called by muse, mutect2, varscan2
- LSS | c.199T>A p.L67M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV100710845; called by muse, varscan2
- NEURL4 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.596); catalogued as COSV59760338; called by muse, mutect2, varscan2
- NOP2 | c.515G>A p.R172Q (on ENST00000322166 / NM_001258308.2; = p.R168Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768153160, COSV59111687; called by muse, mutect2, varscan2
- OPTN | c.1193A>C p.Q398P | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.828); catalogued as COSV53811566; called by muse, mutect2, varscan2
- PCDHA4 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 10/360 reads (3%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1562206749, COSV63540728, COSV63544178; called by muse, mutect2
- PCDHB10 | c.1389C>A p.N463K | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV53380692; called by muse, mutect2, varscan2
- RC3H1 | c.29A>T p.D10V | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51204452; called by muse, mutect2, varscan2
- RECK | c.1313A>T p.E438V | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV65035684; called by muse, mutect2, varscan2
- RNF216 | c.1406G>A p.R469H (on ENST00000425013 / NM_207116.3; = p.R526H on NM_207111.4) | Missense Mutation (SNP) | VAF 125/263 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs996137713, COSV66289036; called by muse, mutect2, varscan2
- SPTBN4 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs781542918, COSV58945265; called by muse, mutect2, varscan2
- TBC1D23 | c.1256T>G p.F419C | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61368708; called by muse, mutect2, varscan2
- TTC17 | c.788T>A p.I263N | Missense Mutation (SNP) | VAF 152/279 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV50011049; called by muse, mutect2, varscan2
- UBOX5 | c.1597A>G p.S533G | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV53906924; called by muse, mutect2, varscan2
- ZKSCAN1 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs144801167; called by muse, mutect2, varscan2
- ZNF749 | c.1282C>G p.H428D | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61946713; called by muse, mutect2, varscan2
- GFPT2 | c.116del p.G39Vfs*40 | Frame Shift Del (DEL) | VAF 185/389 reads (48%) | called by mutect2, pindel, varscan2
- ACBD6 | c.750C>T p.D250= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV62574368; called by muse, mutect2, varscan2
- KIDINS220 | c.861G>A p.A287= | Silent (SNP) | VAF 207/700 reads (30%) | catalogued as rs767614503, COSV56755311; called by muse, mutect2, varscan2
- NES | c.3873C>T p.L1291= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as COSV63960635; called by muse, mutect2, varscan2
- ORC4 | c.1227T>C p.T409= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as COSV51574702; called by muse, mutect2, varscan2
- RBL1 | c.2847C>T p.Y949= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as rs1482096686, COSV60330857; called by muse, mutect2, varscan2
- RICTOR | c.4185G>A p.L1395= | Silent (SNP) | VAF 66/213 reads (31%) | catalogued as COSV57124600; called by muse, mutect2, varscan2
- SEMA3E | c.234A>G p.V78= | Silent (SNP) | VAF 242/465 reads (52%) | catalogued as rs757380130, COSV57096220; called by muse, mutect2, varscan2
- SLC22A23 | c.1791C>T p.Y597= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as COSV66678157; called by muse, mutect2, varscan2
- SLIT3 | c.4056G>A p.V1352= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100266010; called by muse, mutect2, varscan2
- SQSTM1 | c.450G>A p.L150= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV62435075; called by muse, mutect2, varscan2
- TMPRSS3 | c.1332C>T p.I444= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs1416189405, COSV52304599; called by muse, mutect2, varscan2
